FM case AD14494 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/ac5bb1fc-0ea8-4146-a94e-4e99ebe1e54e

Female, 66.3 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Metastatic.
